Somatic mutation profile of tumor specimen C3N-00168-02 (aliquot CPT0019990009) from CPTAC case C3N-00168, project CPTAC-3 (Kidney — Adenomas and Adenocarcinomas). Sex at birth: male; Vital status: Alive; Primary diagnosis: Renal cell carcinoma, NOS; Tissue or organ of origin: Kidney, NOS; AJCC pathologic stage: Stage I; Tumor grade: G3; Age at diagnosis: 47.5 years (17,349 days).
Specimen C3N-00168-02: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Kidney; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 31ea83e3-cf75-40f5-ac42-d818c4fe638d.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-00168-31 (Blood Derived Normal), aliquot CPT0020920002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f3a8b330-5c67-45df-a3ab-ccaacddeee83

The open-access MAF lists 68 somatic variants for this specimen: 50 protein-altering or splice-affecting, 11 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 42, Silent 11, Frame Shift Del 3, Intron 3, Frame Shift Ins 2, Nonsense Mutation 2, 3'Flank 1, Splice Site 1, 3'UTR 1, 5'UTR 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ABCC10 | c.1709G>A p.R570Q (on ENST00000372530 / NM_001198934.2; = p.R527Q on NM_033450.2 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 33/161 reads (20%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs745844891, COSV55085418; called by muse, mutect2, varscan2
- ADTRP | c.197T>A p.V66E | Missense Mutation (SNP) | VAF 47/209 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV57643443; called by muse, mutect2, varscan2
- CDHR5 | c.178G>A p.V60M | Missense Mutation (SNP) | VAF 10/83 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs748626313; called by muse, mutect2, varscan2
- DMXL1 | c.5510A>T p.H1837L | Missense Mutation (SNP) | VAF 39/182 reads (21%) | SIFT tolerated (0.31); PolyPhen benign (0.079); catalogued as rs564680072; called by muse, mutect2, varscan2
- EPHX2 | c.904C>T p.P302S | Missense Mutation (SNP) | VAF 28/166 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs867470047; called by muse, mutect2, varscan2
- GLI2 | c.1970C>A p.A657D (on ENST00000361492 / NM_001374353.1; = p.A674D on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 19/153 reads (12%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.982); catalogued as rs773562626; called by muse, mutect2, varscan2
- KRT32 | c.862A>G p.N288D | Missense Mutation (SNP) | VAF 6/36 reads (17%) | SIFT tolerated (0.31); PolyPhen benign (0.013); catalogued as COSV56785340; called by muse, mutect2
- MYL1 | c.44C>T p.A15V | Missense Mutation (SNP) | VAF 20/204 reads (10%) | SIFT tolerated, low confidence (0.24); PolyPhen benign (0.186); catalogued as rs762562092; called by muse, mutect2, varscan2
- PDPN | c.329C>T p.T110M (on ENST00000621990; = p.T186M on NM_006474.4) | Missense Mutation (SNP) | VAF 14/127 reads (11%) | SIFT tolerated (0.3); PolyPhen benign (0.007); catalogued as rs368396279; called by muse, mutect2
- PRDM14 | c.604C>G p.L202V | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as rs889482883; called by muse, mutect2, varscan2
- RNF133 | c.857G>A p.W286* | Nonsense Mutation (SNP) | VAF 34/148 reads (23%) | catalogued as rs1224943125; called by muse, mutect2, varscan2
- SLC4A10 | c.1127G>T p.G376V (on ENST00000446997 / NM_001354461.2; = p.G346V on NM_022058.4 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55763091; called by muse, mutect2, varscan2
- VHL | c.408dup p.V137Cfs*7 | Frame Shift Ins (INS) | VAF 91/367 reads (25%) | catalogued as COSV56544783, COSV56547644; called by mutect2, pindel, varscan2
- ACTB | c.704C>A p.S235Y | Missense Mutation (SNP) | VAF 100/395 reads (25%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.784); called by muse, mutect2, varscan2
- CHUK | c.1001T>C p.L334P | Missense Mutation (SNP) | VAF 21/105 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.879); called by muse, mutect2, varscan2
- CPNE3 | c.211G>A p.V71M | Missense Mutation (SNP) | VAF 12/81 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.026); called by muse, mutect2, varscan2
- CPNE3 | c.212T>C p.V71A | Missense Mutation (SNP) | VAF 11/80 reads (14%) | SIFT deleterious (0.04); PolyPhen benign (0.014); called by muse, mutect2, varscan2
- CUBN | c.865T>C p.C289R | Missense Mutation (SNP) | VAF 99/508 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- DHFR2 | c.317T>C p.L106S | Missense Mutation (SNP) | VAF 28/216 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.962); called by muse, mutect2, varscan2
- DNAH3 | c.6233C>A p.T2078N | Missense Mutation (SNP) | VAF 12/160 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- EPHA6 | c.1315del p.T439Qfs*23 | Frame Shift Del (DEL) | VAF 22/96 reads (23%) | called by mutect2, pindel, varscan2
- HIVEP2 | c.2025G>A p.M675I | Missense Mutation (SNP) | VAF 59/269 reads (22%) | SIFT tolerated (0.46); PolyPhen benign (0); called by muse, mutect2, varscan2
- HOOK3 | c.858T>G p.N286K | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT deleterious (0); PolyPhen possibly damaging (0.803); called by muse, mutect2, varscan2
- IL21 | c.360+1G>C p.X120_splice | Splice Site (SNP) | VAF 6/44 reads (14%) | called by muse, mutect2
- ITGA2 | c.2726G>C p.S909T | Missense Mutation (SNP) | VAF 16/224 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0.007); called by muse, mutect2
- ITPR2 | c.4588A>C p.K1530Q | Missense Mutation (SNP) | VAF 37/182 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.493); called by muse, mutect2, varscan2
- JAG2 | c.3115A>C p.S1039R | Missense Mutation (SNP) | VAF 60/226 reads (27%) | SIFT tolerated (0.53); PolyPhen benign (0.01); called by muse, mutect2, varscan2
- KCNA10 | c.1322G>T p.C441F | Missense Mutation (SNP) | VAF 21/192 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- KIAA0232 | c.722_732del p.T241Rfs*16 | Frame Shift Del (DEL) | VAF 35/224 reads (16%) | called by mutect2, pindel, varscan2
- LRRC15 | c.856C>T p.P286S | Missense Mutation (SNP) | VAF 20/223 reads (9%) | SIFT tolerated (0.12); PolyPhen possibly damaging (0.597); called by muse, mutect2
- MAST3 | c.560T>A p.M187K | Missense Mutation (SNP) | VAF 46/172 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); called by muse, varscan2
- MUC17 | c.11918C>A p.T3973K | Missense Mutation (SNP) | VAF 39/213 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.535); called by muse, mutect2, varscan2
- NEGR1 | c.284C>A p.T95K | Missense Mutation (SNP) | VAF 46/473 reads (10%) | SIFT tolerated (0.08); PolyPhen benign (0.3); called by muse, mutect2
- NFKBIA | c.854A>G p.D285G | Missense Mutation (SNP) | VAF 34/288 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.219); called by muse, mutect2, varscan2
- NIPAL4 | c.68C>T p.P23L | Missense Mutation (SNP) | VAF 18/102 reads (18%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); called by muse, mutect2, varscan2
- OR51I2 | c.736C>A p.L246M | Missense Mutation (SNP) | VAF 25/166 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); called by muse, mutect2, varscan2
- OVCH1 | c.841T>A p.F281I | Missense Mutation (SNP) | VAF 42/158 reads (27%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- P3H3 | c.1850A>G p.D617G | Missense Mutation (SNP) | VAF 41/175 reads (23%) | SIFT tolerated (0.43); PolyPhen possibly damaging (0.9); called by muse, mutect2, varscan2
- PBRM1 | c.4671dup p.G1558Wfs*58 (on ENST00000296302 / NM_001366071.2; = p.G1451Wfs*58 on NM_018313.5) | Frame Shift Ins (INS) | VAF 11/121 reads (9%) | called by mutect2, pindel, varscan2
- RRP9 | c.508A>G p.I170V | Missense Mutation (SNP) | VAF 27/80 reads (34%) | SIFT tolerated (0.23); PolyPhen benign (0.15); called by muse, mutect2, varscan2
- SEPTIN5 | c.380A>C p.D127A | Missense Mutation (SNP) | VAF 40/147 reads (27%) | SIFT tolerated (0.06); PolyPhen benign (0.318); called by muse, mutect2, varscan2
- SLFN12L | c.1037C>T p.P346L (on ENST00000260908 / NM_001363830.1; = p.P364L on NM_001195790.1) | Missense Mutation (SNP) | VAF 23/59 reads (39%) | SIFT deleterious (0); PolyPhen benign (0.202); called by muse, mutect2, varscan2
- SPNS1 | c.682G>A p.V228M | Missense Mutation (SNP) | VAF 29/234 reads (12%) | SIFT tolerated (0.31); PolyPhen benign (0.213); called by muse, mutect2, varscan2
- THEMIS | c.363G>T p.K121N | Missense Mutation (SNP) | VAF 13/190 reads (7%) | SIFT tolerated (0.21); PolyPhen benign (0.426); called by muse, mutect2
- VCAM1 | c.640G>C p.V214L | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0.01); PolyPhen benign (0); called by muse, varscan2
- YWHAQ | c.649A>G p.I217V | Missense Mutation (SNP) | VAF 33/120 reads (28%) | SIFT deleterious, low confidence (0.05); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- ZNF407 | c.3292G>A p.E1098K | Missense Mutation (SNP) | VAF 25/170 reads (15%) | SIFT tolerated (0.07); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- ZNF735 | c.954T>G p.I318M | Missense Mutation (SNP) | VAF 25/242 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.725); called by muse, mutect2
- ZNF91 | c.2548G>T p.G850* | Nonsense Mutation (SNP) | VAF 26/117 reads (22%) | called by muse, mutect2, varscan2
- ZSWIM7 | c.188_195del p.R63Ifs*9 | Frame Shift Del (DEL) | VAF 41/179 reads (23%) | called by mutect2, pindel, varscan2
- AHSG | c.534C>T p.S178= | Silent (SNP) | VAF 67/373 reads (18%) | called by muse, mutect2, varscan2
- COL26A1 | c.318C>T p.S106= (on ENST00000313669 / NM_001278563.3; = p.S104= on NM_133457.4) | Silent (SNP) | VAF 26/224 reads (12%) | catalogued as COSV58128590; called by muse, mutect2, varscan2
- DMAP1 | c.588C>T p.Y196= | Silent (SNP) | VAF 26/119 reads (22%) | called by muse, mutect2, varscan2
- DOCK6 | c.252G>A p.E84= | Silent (SNP) | VAF 25/99 reads (25%) | called by muse, mutect2, varscan2
- NAV2 | c.2430G>A p.Q810= (on ENST00000396087 / NM_001244963.2; = p.Q787= on NM_145117.5) | Silent (SNP) | VAF 38/176 reads (22%) | catalogued as COSV62337380; called by muse, mutect2, varscan2
- NOX3 | c.1194C>T p.H398= | Silent (SNP) | VAF 24/188 reads (13%) | catalogued as COSV50154316; called by muse, mutect2, varscan2
- PTPRT | c.1620G>T p.G540= | Silent (SNP) | VAF 56/328 reads (17%) | catalogued as COSV61961508; called by muse, mutect2, varscan2
- RALYL | c.144A>C p.I48= | Silent (SNP) | VAF 47/318 reads (15%) | called by muse, mutect2, varscan2
- SLC12A5 | c.507G>A p.T169= (on ENST00000454036 / NM_001134771.2; = p.T146= on NM_020708.5) | Silent (SNP) | VAF 37/176 reads (21%) | catalogued as rs1345353699; called by muse, mutect2, varscan2
- SORBS2 | c.846G>T p.V282= (on ENST00000284776 / NM_021069.5; = p.V375= on NM_003603.6) | Silent (SNP) | VAF 78/250 reads (31%) | called by muse, mutect2, varscan2
- ZFAND3 | c.441T>C p.S147= | Silent (SNP) | VAF 19/110 reads (17%) | called by muse, mutect2, varscan2
- AL669831.6 | chr1:786117 C>T | 3'Flank (SNP) | VAF 39/139 reads (28%) | called by muse, mutect2, varscan2
- CEP41 | c.*2672C>G | 3'UTR (SNP) | VAF 12/258 reads (5%) | catalogued as rs1554414461; called by muse, mutect2
- GLYATL1 | c.-37C>T | 5'UTR (SNP) | VAF 41/235 reads (17%) | called by muse, varscan2
- MIR522 | n.65C>G | RNA (SNP) | VAF 8/152 reads (5%) | called by muse, mutect2
- NALCN | c.2118+16del | Intron (DEL) | VAF 36/232 reads (16%) | called by mutect2, pindel, varscan2
- NCOR1 | c.6680-167C>A | Intron (SNP) | VAF 7/30 reads (23%) | catalogued as rs77840736; called by muse, varscan2
- NDUFC2-KCTD14 | c.311-21440C>T | Intron (SNP) | VAF 51/300 reads (17%) | catalogued as rs1440788637; called by muse, mutect2, varscan2
